CCDI case PBCEWY — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/a7f63cb1-2b09-4f2b-b8d6-2caf16e0c4e9

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Diagnosis record without a diagnosis name: ICD-O-3 morphology code: 9161/1; Tissue or organ of origin: Ventricle, NOS; Age at diagnosis: 20.6 years (7,506 days).

Biospecimens (3 samples)
- Sample 0DQQBR: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DQQC9: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DQQCL: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
